Somatic mutation profile of tumor specimen MMRF_2199_1_BM_CD138pos (aliquot MMRF_2199_1_BM_CD138pos_T1_KHS5U_L08835) from MMRF case MMRF_2199, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.8 years (28,430 days).
Specimen MMRF_2199_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 521874ec-ef01-4c34-8502-6f48f170dc29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2199_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2199_1_PB_Whole_C2_KHS5U_L08782; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a64ff3b-6d8a-4fde-a15a-64b9bf8a7e1c

The open-access MAF lists 139 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 70 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, 3'UTR 42, Silent 17, Intron 13, RNA 7, 3'Flank 3, 5'UTR 3, Nonsense Mutation 2, 5'Flank 2, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1B10 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as rs757758746; called by muse, mutect2, varscan2
- AKR1B15 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.273); catalogued as rs781519182, COSV71151420; called by muse, mutect2, varscan2
- CACNA1H | c.2243C>T p.A748V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770371468, CM032208, COSV61987315; called by muse, mutect2, varscan2
- CCDC87 | c.1608dup p.Q537Tfs*8 | Frame Shift Ins (INS) | VAF 25/218 reads (11%) | catalogued as rs1053211654; called by mutect2, pindel, varscan2
- CEP85L | c.1580A>C p.Q527P | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100874174; called by muse, mutect2, varscan2
- EDNRA | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60096468; called by muse, mutect2, varscan2
- FIGN | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs1558995136; called by muse, mutect2, varscan2
- GTF3C1 | c.2893G>T p.V965L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); catalogued as COSV100648866; called by muse, mutect2, varscan2
- LRRC66 | c.2392A>G p.R798G | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV58636777; called by muse, mutect2, varscan2
- MLIP | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs140282045; called by muse, mutect2, varscan2
- P2RY2 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as rs1365311850, COSV60776552; called by muse, mutect2, varscan2
- PARP2 | c.950C>G p.T317S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV51641892; called by muse, mutect2
- PRM2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs750334799, COSV54113532; called by muse, mutect2, varscan2
- SMARCD2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 139/211 reads (66%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.693); catalogued as rs771732575; called by muse, mutect2, varscan2
- SRSF8 | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 15/338 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV101475776; called by muse, mutect2
- STAC2 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 22/354 reads (6%) | catalogued as COSV61065179; called by muse, mutect2
- TG | c.7991G>C p.R2664T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV55088634; called by muse, mutect2
- UHRF2 | c.23T>C p.I8T | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs774860559; called by muse, mutect2, varscan2
- ZSCAN10 | c.1504C>T p.R502C (on ENST00000252463; = p.R557C on NM_032805.3) | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs779451100, COSV52966710; called by muse, mutect2, varscan2
- ACSM2B | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- ADAMTS12 | c.4123A>T p.K1375* | Nonsense Mutation (SNP) | VAF 35/153 reads (23%) | called by muse, mutect2, varscan2
- ARHGAP45 | c.2155A>C p.S719R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIRC6 | c.10063A>C p.T3355P | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- COLEC10 | c.462A>C p.E154D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COLGALT2 | c.871T>C p.Y291H | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DHX32 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ECPAS | c.1897A>G p.M633V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPS8L2 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- FAM83B | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT13 | c.1296+2T>C p.X432_splice | Splice Site (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- GKN2 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS3ST1 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MYH4 | c.1043A>G p.E348G | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO15B | c.6949T>C p.W2317R | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- NES | c.3701G>C p.G1234A | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); called by muse, mutect2
- NPTX1 | c.993T>A p.D331E | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE11A | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPEF1 | c.1176T>G p.N392K | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRKCQ | c.1368del p.F456Lfs*2 | Frame Shift Del (DEL) | VAF 72/161 reads (45%) | called by mutect2, varscan2
- RIPK2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); called by muse, mutect2
- SH3TC2 | c.3848G>A p.G1283D | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC18A3 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SPATS2L | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- SPEN | c.10727T>C p.L3576P | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UMOD | c.1822G>C p.G608R | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- UNC80 | c.1938C>A p.H646Q | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VWA3A | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WDR6 | c.1627G>A p.V543M | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZC3H12B | c.2375A>T p.Q792L | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF594 | c.2034A>C p.K678N | Missense Mutation (SNP) | VAF 126/201 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- ZNF607 | c.149T>A p.V50E | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ZNRF4 | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2
- ALDH16A1 | c.474G>A p.E158= | Silent (SNP) | VAF 98/163 reads (60%) | called by muse, mutect2, varscan2
- ATG9B | c.2268C>T p.L756= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- ATXN3L | c.630A>G p.E210= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV66075762; called by muse, mutect2
- CELF2 | c.795G>A p.A265= (on ENST00000416382 / NM_001025077.3; = p.A272= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs267602362, COSV59978350; called by muse, mutect2, varscan2
- COL23A1 | c.1542C>A p.G514= | Silent (SNP) | VAF 60/112 reads (54%) | catalogued as COSV66790948, COSV66794765; called by muse, mutect2, varscan2
- FANCG | c.1000C>T p.L334= | Silent (SNP) | VAF 28/97 reads (29%) | called by muse, mutect2
- HSPA12A | c.1422C>A p.T474= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV65024088; called by muse, mutect2, varscan2
- IGHV3-7 | c.313C>T p.L105= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1555429764; called by muse, varscan2
- IGLV2-23 | c.177G>A p.Q59= | Silent (SNP) | VAF 20/20 reads (100%) | catalogued as rs11558640; called by muse, mutect2, varscan2
- IGLV2-23 | c.327C>T p.C109= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs543691170; called by muse, mutect2, varscan2
- MEX3D | c.1365C>T p.F455= | Silent (SNP) | VAF 37/61 reads (61%) | called by muse, mutect2, varscan2
- MGAM2 | c.2001C>T p.T667= | Silent (SNP) | VAF 17/205 reads (8%) | called by muse, mutect2
- RP1L1 | c.5580C>T p.A1860= | Silent (SNP) | VAF 69/281 reads (25%) | catalogued as COSV101223458; called by muse, mutect2, varscan2
- TTC28 | c.4422C>T p.P1474= | Silent (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- UBR5 | c.6504T>G p.S2168= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV55296951; called by muse, mutect2
- UNC80 | c.5022T>C p.P1674= | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- WDR87 | c.8457G>A p.Q2819= | Silent (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- ABCC9 | c.*1313A>C | 3'UTR (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- AC008592.1 | chr5:95858899 A>G | 5'Flank (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- AC106818.1 | n.174C>T | RNA (SNP) | VAF 17/220 reads (8%) | catalogued as rs1404941043; called by muse, mutect2
- ADPGK | c.840+232C>A | Intron (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- AIPL1 | c.*1288C>T | 3'UTR (SNP) | VAF 43/150 reads (29%) | catalogued as rs553220927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMZ2P1 | n.1549G>A | RNA (SNP) | VAF 114/180 reads (63%) | called by muse, varscan2
- ATP2B2 | chr3:10325178 G>A | 3'Flank (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- ATRNL1 | c.-123C>A | 5'UTR (SNP) | VAF 78/157 reads (50%) | called by muse, mutect2, varscan2
- BATF2 | c.*583G>T | 3'UTR (SNP) | VAF 34/227 reads (15%) | called by muse, mutect2, varscan2
- C5orf38 | c.404+79C>T | Intron (SNP) | VAF 53/83 reads (64%) | catalogued as rs566728393; called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949177 T>C | 3'Flank (SNP) | VAF 89/134 reads (66%) | called by muse, mutect2, varscan2
- CCDC144A | c.4098+202T>A | Intron (SNP) | VAF 6/154 reads (4%) | called by muse, mutect2
- CLN5 | chr13:76992084 A>G | 5'Flank (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2
- CLTB | c.*192C>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- COL4A5 | c.-105C>T | 5'UTR (SNP) | VAF 15/31 reads (48%) | catalogued as rs897485595; called by muse, mutect2, varscan2
- DCAF7 | c.*65+127G>A | Intron (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- DDX11 | c.*612C>T | 3'UTR (SNP) | VAF 39/80 reads (49%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.723G>A | RNA (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- EFCAB1 | c.*1034C>A | 3'UTR (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- EIF3M | c.*2174G>T | 3'UTR (SNP) | VAF 16/97 reads (16%) | catalogued as rs946976842; called by muse, mutect2, varscan2
- EXO5 | c.*119dup | 3'UTR (INS) | VAF 12/39 reads (31%) | catalogued as rs1436157403; called by mutect2, varscan2
- FAM126A | c.*2231G>C | 3'UTR (SNP) | VAF 75/104 reads (72%) | called by muse, mutect2, varscan2
- FAM90A27P | n.499C>T | RNA (SNP) | VAF 31/116 reads (27%) | catalogued as rs751884107; called by muse, mutect2, varscan2
- FGF20 | c.*729G>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as rs550273218; called by muse, mutect2
- FKBP15 | c.*4167C>T | 3'UTR (SNP) | VAF 56/171 reads (33%) | called by muse, mutect2
- FKBP15 | c.*4165C>T | 3'UTR (SNP) | VAF 55/167 reads (33%) | called by muse, mutect2
- FRS2 | c.*1058T>G | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- GNPNAT1 | c.*1757A>T | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- HEMGN | c.*300del | 3'UTR (DEL) | VAF 7/59 reads (12%) | catalogued as rs1191128833; called by mutect2, pindel, varscan2
- HSD3B7 | c.322+60C>T | Intron (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- HSD3B7 | c.531+22G>A | Intron (SNP) | VAF 78/131 reads (60%) | catalogued as rs180789410; called by muse, mutect2, varscan2
- INHBA | c.*453C>G | 3'UTR (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- JAZF1 | c.*2025T>G | 3'UTR (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- KIAA0319 | c.*1612G>T | 3'UTR (SNP) | VAF 28/46 reads (61%) | called by muse, mutect2, varscan2
- LINC00868 | n.602C>G | RNA (SNP) | VAF 56/100 reads (56%) | called by muse, mutect2, varscan2
- MAN1A2 | c.*2620A>G | 3'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- NAA15 | c.*1823G>A | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- NAT8L | c.*251C>T | 3'UTR (SNP) | VAF 12/99 reads (12%) | catalogued as rs1308613142; called by muse, mutect2, varscan2
- NBPF3 | c.*323T>G | 3'UTR (SNP) | VAF 6/24 reads (25%) | catalogued as rs200265424; called by muse, mutect2
- PCBP4 | c.*92C>A | 3'UTR (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- PCDH15 | c.*3489del | 3'UTR (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- PDE6C | c.*136T>C | 3'UTR (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- PLP1 | c.*658C>A | 3'UTR (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- PROX2 | c.*552C>G | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- PRPF31 | c.-8-19C>T | Intron (SNP) | VAF 31/111 reads (28%) | catalogued as rs373990452; called by muse, mutect2, varscan2
- PSAPL1 | c.*2647C>T | 3'UTR (SNP) | VAF 100/335 reads (30%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22602703 T>G | 3'Flank (SNP) | VAF 115/193 reads (60%) | called by muse, mutect2, varscan2
- RNF166 | c.*136C>T | 3'UTR (SNP) | VAF 50/70 reads (71%) | called by muse, mutect2, varscan2
- RPL5 | c.4-607G>A | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- SCRN3 | c.*1069C>A | 3'UTR (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- SCUBE3 | c.*1645G>T | 3'UTR (SNP) | VAF 43/81 reads (53%) | catalogued as rs1324997024; called by muse, mutect2, varscan2
- SH3BP5L | c.*1051C>T | 3'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- SLC17A7 | c.63-67C>A | Intron (SNP) | VAF 38/58 reads (66%) | called by muse, mutect2, varscan2
- SLC6A11 | c.623+1230A>G | Intron (SNP) | VAF 18/103 reads (17%) | catalogued as rs576540647; called by muse, mutect2, varscan2
- SLITRK1 | c.*199G>T | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- SOX11 | c.*7321T>A | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- SOX5 | c.*3790G>C | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- SV2B | c.*4513C>T | 3'UTR (SNP) | VAF 18/357 reads (5%) | called by muse, mutect2
- TCP10L2 | n.158T>G | RNA (SNP) | VAF 86/175 reads (49%) | called by muse, mutect2, varscan2
- TDGF1P3 | n.523G>A | RNA (SNP) | VAF 66/166 reads (40%) | called by muse, mutect2, varscan2
- TMEFF2 | c.439+1297G>A | Intron (SNP) | VAF 22/56 reads (39%) | catalogued as rs775211303; called by muse, mutect2, varscan2
- TPD52 | c.506+41A>T | Intron (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- TSLP | c.*1140T>G | 3'UTR (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- TUSC3 | c.*1934G>A | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- VPS13A | c.*2486C>G | 3'UTR (SNP) | VAF 14/73 reads (19%) | catalogued as rs559212362; called by mutect2, varscan2
- VPS51 | c.-27T>A | 5'UTR (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- VTI1B | c.*3377_*3379del | 3'UTR (DEL) | VAF 6/78 reads (8%) | called by mutect2, pindel
- ZNF138 | c.*1346A>G | 3'UTR (SNP) | VAF 13/122 reads (11%) | catalogued as rs1300925418; called by muse, mutect2, varscan2
- ZNF318 | c.*506G>T | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- ZNF789 | c.151+611C>A | Intron (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
